Somatic mutation profile of tumor specimen TCGA-BA-4076-01A (aliquot TCGA-BA-4076-01A-01D-1434-08) from TCGA case TCGA-BA-4076, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G2; Age at diagnosis: 39.4 years (14,405 days).
Specimen TCGA-BA-4076-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2581a259-bfd4-4796-9b7b-c9f56e63e681.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-4076-10A (Blood Derived Normal), aliquot TCGA-BA-4076-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca760ad9-3a17-4595-8b30-1f673516145c

The open-access MAF lists 357 somatic variants for this specimen: 271 protein-altering or splice-affecting, 77 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 235, Silent 77, Nonsense Mutation 18, Splice Site 9, RNA 5, Frame Shift Del 5, Frame Shift Ins 3, Intron 2, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373715782, CM051829; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD40LG | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193922136, CM960264, COSV101033584, COSV65699024; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.594+1G>T p.X198_splice | Splice Site (SNP) | VAF 42/105 reads (40%) | catalogued as rs1057516470, COSV100219450, COSV100225425; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.407A>C p.Q136P | Missense Mutation (SNP) | VAF 25/65 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1567554216, COSV52751724, COSV52782611, COSV52910696, COSV53122800; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 86/228 reads (38%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99789565; called by muse, mutect2, varscan2
- ACSM5 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100088795; called by muse, mutect2, varscan2
- ADAMTS15 | c.2747G>T p.R916L | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100143308, COSV54510065; called by muse, mutect2, varscan2
- ADAMTS3 | c.2485G>C p.D829H | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99710861; called by muse, mutect2, varscan2
- ADGRA1 | c.260G>T p.W87L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101658601; called by muse, mutect2
- ADGRB1 | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100029539; called by muse, mutect2, varscan2
- ADGRF5 | c.221C>A p.A74E | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV99345435; called by muse, mutect2, varscan2
- AHCYL2 | c.1108A>T p.N370Y | Missense Mutation (SNP) | VAF 117/170 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100273292; called by muse, mutect2, varscan2
- AHNAK | c.2248C>G p.P750A | Missense Mutation (SNP) | VAF 163/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99947004; called by muse, mutect2, varscan2
- ALB | c.1752G>T p.K584N | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV99891280; called by muse, mutect2, varscan2
- ALB | c.1753G>T p.A585S | Missense Mutation (SNP) | VAF 72/218 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.859); catalogued as rs993669078, COSV99891284; called by muse, mutect2, varscan2
- ALOX5 | c.1924C>A p.L642I | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65552580; called by muse, mutect2, varscan2
- ANK2 | c.8092A>T p.S2698C | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); catalogued as COSV100001082; called by muse, mutect2, varscan2
- ANKRD45 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100322467; called by muse, mutect2, varscan2
- ANTXR2 | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100226484; called by muse, mutect2, varscan2
- AP002512.3 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1298463297, COSV99039480; called by muse, mutect2, varscan2
- ARFGEF3 | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 265/309 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV99293188; called by muse, mutect2, varscan2
- ARHGAP17 | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV99253291; called by muse, mutect2, varscan2
- ARHGAP28 | c.1327G>T p.D443Y (on ENST00000383472 / NM_001366230.1; = p.D284Y on NM_001010000.3) | Missense Mutation (SNP) | VAF 133/223 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99149886; called by muse, mutect2, varscan2
- ARMC4 | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 35/86 reads (41%) | catalogued as COSV59462231; called by muse, mutect2, varscan2
- ASXL3 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs369560043; called by muse, mutect2, varscan2
- ASXL3 | c.6444G>T p.Q2148H | Missense Mutation (SNP) | VAF 230/351 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV99324540; called by muse, mutect2, varscan2
- ATAD5 | c.4912T>A p.C1638S | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100429886; called by muse, mutect2, varscan2
- ATP7A | c.3655G>T p.D1219Y | Missense Mutation (SNP) | VAF 64/83 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430650; called by muse, mutect2, varscan2
- ATP7B | c.2887C>A p.Q963K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.006); catalogued as CD033174, CM032849, COSV99666328; called by muse, mutect2, varscan2
- ATRNL1 | c.2882G>T p.C961F | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100370253, COSV58089644; called by muse, mutect2, varscan2
- BARHL1 | c.731T>A p.L244Q | Missense Mutation (SNP) | VAF 211/246 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99707553; called by muse, mutect2, varscan2
- BARX2 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858547; called by muse, mutect2, varscan2
- BDNF | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370382246; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3818G>T p.R1273L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100863553; called by muse, mutect2, varscan2
- C22orf39 | c.259C>G p.P87A | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100286977; called by muse, mutect2, varscan2
- C6 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as COSV99666936; called by muse, mutect2, varscan2
- CADM2 | c.94G>T p.V32L (on ENST00000407528 / NM_001167674.2; = p.V34L on NM_153184.4) | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV101054503; called by muse, mutect2, varscan2
- CASP6 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488661; called by muse, mutect2, varscan2
- CCNE1 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV99388353; called by muse, mutect2, varscan2
- CD163 | c.2834G>C p.W945S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775802, COSV63133200; called by muse, mutect2, varscan2
- CELA2A | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100657529; called by muse, mutect2, varscan2
- CFHR5 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.047); catalogued as rs1377428392, COSV99888510, COSV99889916; called by muse, mutect2, varscan2
- CGB2 | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199611687, COSV100031610; called by muse, varscan2
- CHRD | c.297C>G p.C99W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99200370; called by muse, mutect2, varscan2
- CNTNAP2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.863); catalogued as COSV100665182, COSV62208741; called by muse, mutect2, varscan2
- CNTNAP5 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV101443407; called by muse, mutect2, varscan2
- CNTNAP5 | c.1485C>A p.D495E | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.348); catalogued as rs752582069, COSV101443408; called by muse, mutect2, varscan2
- COL11A1 | c.2885C>A p.P962H | Missense Mutation (SNP) | VAF 87/274 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as rs1192133331, COSV62202037; called by muse, mutect2, varscan2
- COL4A5 | c.4301C>T p.T1434I | Missense Mutation (SNP) | VAF 108/136 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV100087428; called by muse, mutect2, varscan2
- CRACD | c.224T>A p.L75Q | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99949080; called by muse, mutect2, varscan2
- CSMD1 | c.8582G>A p.G2861E (on ENST00000520002; = p.G2860E on NM_033225.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100146858; called by muse, mutect2, varscan2
- CSN1S1 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs370575111; called by muse, mutect2, varscan2
- CWF19L2 | c.1047A>T p.R349S | Missense Mutation (SNP) | VAF 59/87 reads (68%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99978849; called by muse, mutect2, varscan2
- CYP27C1 | c.857C>A p.A286D | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58866166; called by muse, mutect2, varscan2
- DBH | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV99708016; called by muse, mutect2, varscan2
- DGKK | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782159939, COSV101052963; called by muse, mutect2, varscan2
- DGKK | c.2436G>C p.Q812H | Missense Mutation (SNP) | VAF 125/153 reads (82%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV101052964; called by muse, mutect2, varscan2
- DIP2A | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.698); catalogued as COSV59478236; called by muse, mutect2, varscan2
- DKK1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100906528; called by muse, mutect2, varscan2
- DKK2 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53398987; called by muse, mutect2, varscan2
- DNAH5 | c.11536C>T p.Q3846* | Nonsense Mutation (SNP) | VAF 71/269 reads (26%) | catalogued as rs1443845070, COSV99448633; called by muse, mutect2, varscan2
- DNAJB11 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408603; called by muse, mutect2, varscan2
- EFCAB12 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100394572; called by muse, mutect2, varscan2
- EIF2B3 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 88/209 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100838937; called by muse, mutect2, varscan2
- EIF6 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 36/93 reads (39%) | catalogued as COSV99863777; called by muse, mutect2, varscan2
- ELMO1 | c.79-1G>A p.X27_splice | Splice Site (SNP) | VAF 462/530 reads (87%) | catalogued as COSV100164122; called by muse, mutect2, varscan2
- ENPEP | c.1249G>T p.G417* | Nonsense Mutation (SNP) | VAF 64/158 reads (41%) | catalogued as COSV99487485; called by muse, mutect2, varscan2
- ENPP3 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as COSV100717123, COSV100717206; called by muse, mutect2, varscan2
- EP300 | c.7135A>C p.N2379H | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.352); catalogued as rs202225885; called by muse, mutect2, varscan2
- ERICH3 | c.1129G>T p.G377* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV100444076; called by muse, mutect2, varscan2
- ESD | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as COSV101099126; called by muse, mutect2, varscan2
- EYS | c.197T>A p.I66K | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100676288, COSV60985001; called by muse, mutect2, varscan2
- F5 | c.3682C>T p.Q1228* | Nonsense Mutation (SNP) | VAF 197/461 reads (43%) | catalogued as COSV100889060; called by muse, mutect2, varscan2
- FAM122A | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 81/94 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99598599; called by muse, mutect2, varscan2
- FAM161A | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as COSV100281225; called by muse, mutect2, varscan2
- FAM227B | c.1048C>A p.P350T | Missense Mutation (SNP) | VAF 216/271 reads (80%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as COSV100174841; called by muse, mutect2, varscan2
- FAM47B | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV100264270; called by muse, mutect2, varscan2
- FBXL6 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs201941787; called by muse, mutect2
- FBXO21 | c.1298A>G p.Y433C | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100401696; called by muse, mutect2, varscan2
- FHL5 | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.719); catalogued as COSV100459331, COSV58737031; called by muse, mutect2, varscan2
- FIGN | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 47/72 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.445); catalogued as COSV100292194; called by muse, mutect2, varscan2
- FKBP15 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs769214308, COSV99438646; called by muse, mutect2, varscan2
- FLNC | c.1237G>C p.V413L | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT tolerated (0.26); PolyPhen benign (0.213); catalogued as COSV100367966; called by muse, mutect2, varscan2
- FRK | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 141/207 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101661765; called by muse, mutect2, varscan2
- FRMPD4 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 99/128 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101042681; called by muse, mutect2, varscan2
- GABRG2 | c.499A>T p.N167Y | Missense Mutation (SNP) | VAF 151/170 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729654; called by muse, mutect2, varscan2
- GALNT14 | c.803G>T p.R268L | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201375957, COSV100204474; called by muse, mutect2, varscan2
- GALNT6 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100695410; called by muse, mutect2, varscan2
- GALNTL6 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101550691, COSV72552914; called by muse, mutect2, varscan2
- GALNTL6 | c.247+1G>T p.X83_splice | Splice Site (SNP) | VAF 17/35 reads (49%) | catalogued as rs769919518, COSV101560228, COSV72490788; called by muse, mutect2, varscan2
- GOLGA3 | c.3032A>G p.Q1011R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs755150138, COSV99202922; called by muse, mutect2, varscan2
- GPR158 | c.1993C>A p.P665T | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100893342; called by muse, mutect2, varscan2
- GPR158 | c.1994C>A p.P665Q | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100893344; called by muse, mutect2, varscan2
- GPRIN3 | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310707; called by muse, mutect2, varscan2
- GRB14 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 49/68 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.396); catalogued as rs764926149, COSV99813940; called by muse, mutect2, varscan2
- GRM7 | c.1225C>A p.Q409K | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100736177, COSV63169772; called by muse, varscan2
- HEPHL1 | c.3276C>A p.N1092K | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100243839, COSV59889234; called by muse, mutect2, varscan2
- HIPK3 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100305648; called by muse, mutect2, varscan2
- HLTF | c.1237A>C p.K413Q | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV100026803; called by muse, mutect2, varscan2
- HLTF | c.513G>T p.L171F | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV100026805; called by muse, mutect2, varscan2
- HSPG2 | c.9052+1G>T p.X3018_splice | Splice Site (SNP) | VAF 25/73 reads (34%) | catalogued as COSV101013430, COSV65932776, COSV65932908; called by muse, mutect2, varscan2
- IGHV4-34 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs3814933; called by muse, mutect2, varscan2
- INTS1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs370002614; called by muse, varscan2
- IPMK | c.1154A>G p.D385G | Missense Mutation (SNP) | VAF 102/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880290; called by muse, mutect2, varscan2
- IQCC | c.301A>C p.M101L | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV99356512; called by muse, mutect2, varscan2
- IQCJ | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 231/397 reads (58%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV101188310; called by muse, mutect2, varscan2
- IVL | c.1703C>A p.P568H | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100908149; called by muse, mutect2, varscan2
- JPH1 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100646547, COSV60610627; called by muse, mutect2, varscan2
- KAT5 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.123); catalogued as COSV100383890; called by muse, mutect2, varscan2
- KCNJ12 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100054494; called by muse, mutect2, varscan2
- KIAA1217 | c.2131A>T p.R711* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as COSV56817357; called by muse, mutect2, varscan2
- KIF20B | c.1558A>C p.I520L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV99589856; called by muse, mutect2, varscan2
- KIR3DL1 | c.1262C>A p.P421H | Missense Mutation (SNP) | VAF 199/278 reads (72%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.942); catalogued as rs1284896347, COSV100373005; called by muse, varscan2
- KLHL1 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100917155; called by muse, mutect2, varscan2
- KLHL7 | c.151C>G p.Q51E (on ENST00000339077 / NM_001031710.3; = p.Q3E on NM_018846.5) | Missense Mutation (SNP) | VAF 119/132 reads (90%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV100177974; called by muse, mutect2, varscan2
- KRTAP12-2 | c.265A>G p.S89G | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as COSV100553055; called by muse, mutect2, varscan2
- LAMA1 | c.3056A>G p.H1019R | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101056008; called by muse, mutect2, varscan2
- LAMB4 | c.5108T>C p.L1703S | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99223710; called by muse, mutect2, varscan2
- LCT | c.3940G>A p.V1314I | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV99929260; called by muse, mutect2, varscan2
- LEFTY2 | c.269T>A p.L90Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100832572; called by muse, mutect2, varscan2
- LOXL3 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99239637; called by muse, mutect2, varscan2
- LRIT1 | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100928067; called by muse, mutect2, varscan2
- LRP1B | c.1958A>G p.D653G | Missense Mutation (SNP) | VAF 55/74 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101255660; called by muse, mutect2, varscan2
- LRRIQ1 | c.2175G>T p.M725I | Missense Mutation (SNP) | VAF 258/649 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV101280056; called by muse, mutect2, varscan2
- LRRIQ3 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 89/228 reads (39%) | catalogued as COSV100598686; called by muse, mutect2, varscan2
- LRRTM1 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99702307; called by muse, mutect2, varscan2
- LRRTM1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99702312; called by muse, mutect2, varscan2
- LRRTM4 | c.1195T>C p.F399L | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV101297523; called by muse, mutect2, varscan2
- MACC1 | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 506/563 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100255669; called by muse, mutect2, varscan2
- MAGEC1 | c.737T>A p.L246Q | Missense Mutation (SNP) | VAF 223/309 reads (72%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV99595484; called by muse, mutect2, varscan2
- MAP3K5 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1277608111, COSV100752713; called by muse, mutect2, varscan2
- MCM5 | c.703G>T p.A235S | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV99331636; called by muse, mutect2, varscan2
- ME3 | c.991G>T p.V331L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV100660914, COSV62774717; called by muse, mutect2, varscan2
- MEGF6 | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV100742130; called by muse, mutect2, varscan2
- MFN1 | c.1225-1G>A p.X409_splice | Splice Site (SNP) | VAF 46/153 reads (30%) | catalogued as COSV99764387; called by muse, varscan2
- MINAR1 | c.1344G>C p.K448N | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV100548839; called by muse, mutect2, varscan2
- MLH3 | c.3664G>C p.V1222L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV99470124; called by muse, varscan2
- MORC1 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV51718997, COSV51732652; called by muse, mutect2, varscan2
- MROH2B | c.1594G>C p.G532R | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.204); catalogued as COSV101270637; called by muse, mutect2, varscan2
- MUC16 | c.16411A>G p.I5471V | Missense Mutation (SNP) | VAF 147/169 reads (87%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.01); catalogued as rs752957588, COSV101199513; called by muse, mutect2, varscan2
- MYC | c.1140G>T p.Q380H (on ENST00000377970; = p.Q395H on NM_002467.6) | Missense Mutation (SNP) | VAF 107/446 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as COSV52368869, COSV52375011, COSV99420160; called by muse, mutect2, varscan2
- MYCT1 | c.327C>G p.S109R | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100924056; called by muse, mutect2, varscan2
- MYH15 | c.1370G>A p.R457K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV99843028; called by muse, mutect2, varscan2
- MYO1D | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1222135213, COSV100554111; called by muse, mutect2, varscan2
- NAA11 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as COSV99727318; called by muse, mutect2, varscan2
- NAALAD2 | c.958G>T p.G320* | Nonsense Mutation (SNP) | VAF 55/81 reads (68%) | catalogued as rs765763172, COSV100428367, COSV58965070; called by muse, mutect2, varscan2
- NAV3 | c.1645A>G p.K549E | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as COSV99889717; called by muse, mutect2, varscan2
- NEURL4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761211941, COSV59756469; called by muse, mutect2, varscan2
- NLRP11 | c.2711C>G p.A904G | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100789711, COSV64087214; called by muse, mutect2, varscan2
- NLRP14 | c.2456G>C p.R819T | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100204861; called by muse, mutect2
- NLRP4 | c.2713T>A p.L905I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.346); catalogued as rs765085918, COSV100016143; called by muse, mutect2, varscan2
- NLRP5 | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV101173593; called by muse, mutect2, varscan2
- NOTCH1 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53033864, COSV53063079, COSV99487194; called by muse, mutect2, varscan2
- NPAP1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT tolerated (0.92); PolyPhen benign (0.298); catalogued as rs139493881, COSV100275232; called by muse, mutect2, varscan2
- NPAP1 | c.1309C>A p.L437I | Missense Mutation (SNP) | VAF 128/152 reads (84%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV100275234; called by muse, mutect2, varscan2
- NPC1 | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 169/225 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341203; called by muse, mutect2, varscan2
- NPHP3 | c.2724G>A p.W908* | Nonsense Mutation (SNP) | VAF 80/261 reads (31%) | catalogued as rs1238123587, COSV100446824; called by muse, mutect2, varscan2
- NPHS2 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100858158; called by muse, mutect2, varscan2
- NPY5R | c.714A>G p.I238M | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100642750; called by muse, mutect2, varscan2
- NTSR2 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as rs371327070; called by muse, mutect2, varscan2
- OCA2 | c.1273A>T p.M425L | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT tolerated (0.72); PolyPhen benign (0.124); catalogued as COSV100667509; called by muse, mutect2, varscan2
- OPCML | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100100298; called by muse, mutect2, varscan2
- OR14J1 | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 308/392 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101012760; called by muse, mutect2, varscan2
- OR1S2 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.166); catalogued as COSV100224134; called by muse, mutect2, varscan2
- OR2M7 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 149/397 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs1164499945, COSV58739263; called by muse, mutect2, varscan2
- OR4A16 | c.255T>A p.C85* | Nonsense Mutation (SNP) | VAF 146/380 reads (38%) | catalogued as COSV100125169, COSV59041738; called by muse, mutect2, varscan2
- OR4D6 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271671; called by muse, mutect2, varscan2
- OR5AP2 | c.422T>A p.L141H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.838); catalogued as COSV100266165; called by muse, mutect2, varscan2
- OR5D18 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100450649, COSV61736307; called by muse, mutect2, varscan2
- OR5F1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99558554; called by muse, mutect2, varscan2
- OR5I1 | c.216C>A p.D72E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100041369; called by muse, mutect2, varscan2
- OR6C74 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100667726; called by muse, mutect2, varscan2
- PCDH10 | c.2782C>A p.R928S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as COSV99993402; called by muse, mutect2, varscan2
- PCDHA13 | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 126/149 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV56539714, COSV99165845; called by muse, mutect2, varscan2
- PCDHB6 | c.1871C>A p.T624N | Missense Mutation (SNP) | VAF 77/100 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs782447100, COSV99170077; called by muse, mutect2, varscan2
- PDE3A | c.2927G>C p.G976A | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100762048; called by muse, mutect2, varscan2
- PDZD8 | c.2210A>G p.E737G | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100559495; called by muse, mutect2, varscan2
- PER1 | c.3765A>T p.Q1255H | Missense Mutation (SNP) | VAF 202/513 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100424471; called by muse, mutect2, varscan2
- PER1 | c.3764A>T p.Q1255L | Missense Mutation (SNP) | VAF 201/507 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100424474; called by muse, mutect2, varscan2
- PEX19 | c.683T>C p.I228T | Missense Mutation (SNP) | VAF 143/357 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100926944; called by muse, mutect2, varscan2
- PFKFB2 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 64/184 reads (35%) | PolyPhen benign (0.012); catalogued as COSV100891933; called by muse, mutect2, varscan2
- PGBD5 | c.816C>A p.F272L (on ENST00000525115; = p.F341L on NM_001258311.2) | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100358539; called by muse, mutect2, varscan2
- PKHD1 | c.3359T>C p.I1120T | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100582653, COSV61875178; called by muse, mutect2, varscan2
- PKHD1L1 | c.6875G>C p.G2292A | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005990; called by muse, mutect2, varscan2
- PKHD1L1 | c.10448C>A p.T3483K | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101005993; called by muse, mutect2, varscan2
- PLD5 | c.411G>T p.M137I (on ENST00000442594; = p.M75I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV100139953; called by muse, mutect2, varscan2
- PPP1R9A | c.1504C>A p.L502I | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV99195366; called by muse, mutect2, varscan2
- PRKCB | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100333436; called by muse, mutect2, varscan2
- PROS1 | c.896T>A p.L299* | Nonsense Mutation (SNP) | VAF 88/363 reads (24%) | catalogued as COSV101260406; called by muse, mutect2, varscan2
- PTF1A | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100919580; called by muse, mutect2, varscan2
- PTGER2 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55418494; called by muse, mutect2, varscan2
- PTX4 | c.1071C>A p.D357E (on ENST00000447419 / NM_001328608.2; = p.D352E on NM_001013658.1) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99560386; called by muse, mutect2, varscan2
- RBL2 | c.1987C>G p.P663A | Missense Mutation (SNP) | VAF 81/151 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100043561; called by muse, mutect2, varscan2
- RCAN2 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.58); catalogued as COSV100149561; called by muse, mutect2, varscan2
- RGS21 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101314013; called by muse, mutect2, varscan2
- RNF6 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100644621; called by muse, mutect2, varscan2
- ROCK1 | c.1275G>T p.Q425H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101296343; called by muse, mutect2, varscan2
- RPS13 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99930529; called by muse, mutect2, varscan2
- RYR2 | c.12929G>A p.C4310Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100769622, COSV63674252; called by muse, mutect2, varscan2
- SCML2 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99318870; called by muse, mutect2, varscan2
- SCN1A | c.4409G>T p.G1470V (on ENST00000303395 / NM_001202435.3; = p.G1459V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57694180; called by muse, mutect2, varscan2
- SELL | c.977G>C p.S326T (on ENST00000650983; = p.S313T on NM_000655.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs1325491652, COSV52552566, COSV99357490; called by muse, mutect2, varscan2
- SERPING1 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 61/170 reads (36%) | catalogued as COSV99557947; called by muse, mutect2, varscan2
- SERTM1 | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100171287; called by muse, mutect2, varscan2
- SFXN2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs201929596, COSV100882728, COSV64011826; called by muse, mutect2, varscan2
- SHANK2 | c.3328G>T p.E1110* | Nonsense Mutation (SNP) | VAF 45/796 reads (6%) | catalogued as COSV99573481; called by muse, mutect2
- SI | c.3188A>G p.Y1063C | Missense Mutation (SNP) | VAF 151/503 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015174; called by muse, mutect2, varscan2
- SIGLEC9 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.87); catalogued as COSV99142519; called by muse, mutect2, varscan2
- SLC17A6 | c.199C>A p.L67M | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV99581292, COSV99581409; called by muse, mutect2, varscan2
- SLC27A2 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs747898521, COSV99982781; called by muse, mutect2, varscan2
- SLC35F5 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV99829999; called by muse, mutect2, varscan2
- SLC39A12 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101070024; called by muse, mutect2, varscan2
- SLC44A1 | c.1564C>G p.L522V | Missense Mutation (SNP) | VAF 112/266 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1289936464, COSV100570329, COSV58264145; called by muse, mutect2, varscan2
- SLC6A15 | c.2044C>T p.P682S | Missense Mutation (SNP) | VAF 96/256 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99880603; called by muse, mutect2, varscan2
- SLITRK1 | c.715G>T p.V239L | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as COSV100999912; called by muse, mutect2, varscan2
- SPHKAP | c.1974del p.S659Qfs*18 | Frame Shift Del (DEL) | VAF 91/177 reads (51%) | catalogued as COSV100764514; called by mutect2, pindel, varscan2
- SSTR1 | c.701T>A p.L234Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.903); catalogued as COSV99942853; called by muse, mutect2, varscan2
- SSTR3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.908); catalogued as COSV100142630; called by muse, mutect2, varscan2
- ST3GAL6 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV54583495, COSV99504752; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 73/149 reads (49%) | PolyPhen benign (0.387); catalogued as COSV100082745; called by muse, mutect2, varscan2
- STIP1 | c.1121-1G>T p.X374_splice | Splice Site (SNP) | VAF 170/398 reads (43%) | catalogued as COSV100534834; called by muse, mutect2, varscan2
- STUB1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV99555612; called by muse, mutect2, varscan2
- SYNE1 | c.25115G>A p.G8372D (on ENST00000367255 / NM_182961.4; = p.G8324D on NM_033071.3) | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99561230; called by muse, mutect2, varscan2
- SYPL2 | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as COSV100881432; called by muse, mutect2, varscan2
- TAS2R19 | c.562T>G p.F188V | Missense Mutation (SNP) | VAF 113/270 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV101114631; called by muse, varscan2
- TAS2R7 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99553739; called by muse, mutect2, varscan2
- TBC1D15 | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV100041672; called by muse, mutect2, varscan2
- TBCE | c.871G>T p.A291S (on ENST00000366601; = p.A354S on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100783033; called by muse, mutect2, varscan2
- TBX5 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100091069, COSV59865398; called by muse, mutect2, varscan2
- TECRL | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV101168783, COSV67085734; called by muse, mutect2, varscan2
- TFAP2D | c.1157T>A p.F386Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99145865; called by muse, mutect2, varscan2
- TIE1 | c.1115G>C p.C372S | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200472468, COSV100992052, COSV65248348; called by muse, mutect2, varscan2
- TRIOBP | c.1177C>G p.P393A | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV100730812; called by muse, mutect2, varscan2
- TSR1 | c.558A>T p.T186= | Splice Region (SNP) | VAF 84/188 reads (45%) | catalogued as COSV99280046; called by muse, mutect2, varscan2
- TTC5 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 253/447 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV99351738; called by muse, mutect2, varscan2
- TTN | c.57518G>T p.R19173I (on ENST00000591111; = p.R11749I on NM_003319.4) | Missense Mutation (SNP) | VAF 104/348 reads (30%) | PolyPhen possibly damaging (0.804); catalogued as COSV100607402, COSV60283900; called by muse, mutect2, varscan2
- TTN | c.33739G>T p.E11247* (on ENST00000591111; = p.E10320* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 123/538 reads (23%) | catalogued as COSV100607412; called by muse, mutect2, varscan2
- TTN | c.19688C>A p.A6563D (on ENST00000591111; = p.A5636D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/132 reads (57%) | PolyPhen benign (0.049); catalogued as COSV100588980, COSV100607418; called by muse, mutect2, varscan2
- UBXN6 | c.105G>T p.K35N | Missense Mutation (SNP) | VAF 147/197 reads (75%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as COSV100011809; called by muse, mutect2, varscan2
- UGT2B10 | c.276G>T p.L92F | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs1362809119, COSV55319396, COSV99608203; called by muse, mutect2, varscan2
- UNC13C | c.3742C>A p.Q1248K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.97); catalogued as COSV52920694; called by muse, varscan2
- USH2A | c.11386C>G p.P3796A | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100233217; called by muse, mutect2, varscan2
- USH2A | c.3329T>C p.F1110S | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV100233219; called by muse, mutect2, varscan2
- UTP4 | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 539/649 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100076931; called by muse, mutect2, varscan2
- VCAM1 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV54120032, COSV99658449; called by muse, mutect2, varscan2
- VPS13D | c.12712G>C p.G4238R | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99166228; called by muse, mutect2, varscan2
- YWHAZ | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV62053660; called by muse, mutect2, varscan2
- ZC3H14 | c.942G>T p.E314D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV99193014; called by muse, mutect2, varscan2
- ZFHX4 | c.9803C>G p.P3268R | Missense Mutation (SNP) | VAF 73/107 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51506448, COSV99261630; called by muse, mutect2, varscan2
- ZFYVE9 | c.2035G>T p.G679* | Nonsense Mutation (SNP) | VAF 87/224 reads (39%) | catalogued as COSV55098725, COSV99819479; called by muse, mutect2, varscan2
- ZIM3 | c.539C>G p.S180* | Nonsense Mutation (SNP) | VAF 254/440 reads (58%) | catalogued as rs760335482, COSV99517999, COSV99518403; called by muse, mutect2, varscan2
- ZNF208 | c.2075C>A p.P692H | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101236996; called by muse, varscan2
- ZNF23 | c.683A>G p.E228G | Missense Mutation (SNP) | VAF 60/751 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100612120; called by muse, mutect2
- ZNF264 | c.1112A>C p.Y371S | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99567209; called by muse, mutect2, varscan2
- ZNF451 | c.2816G>T p.G939V (on ENST00000370706 / NM_001031623.3; = p.G891V on NM_015555.2) | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100674856; called by muse, mutect2, varscan2
- ZNF98 | c.1055G>A p.C352Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1369048571, COSV100757420; called by mutect2, varscan2
- ZNF99 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101233808; called by muse, mutect2, varscan2
- ZP2 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs756528109, COSV99559395; called by muse, mutect2, varscan2
- ADGRG7 | c.257_258insTT p.M86Ifs*45 | Frame Shift Ins (INS) | VAF 30/147 reads (20%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 107/358 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GRIK4 | c.504dup p.A169Sfs*28 | Frame Shift Ins (INS) | VAF 98/175 reads (56%) | called by mutect2, pindel, varscan2
- IGHV3-48 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); called by muse, varscan2
- IGKV2D-30 | c.317A>T p.E106V | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- KMT2D | c.1960del p.S654Pfs*276 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- LILRB2 | c.875del p.G292Afs*25 | Frame Shift Del (DEL) | VAF 40/100 reads (40%) | called by mutect2, pindel, varscan2
- PLXND1 | c.2637del p.P880Lfs*20 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel
- POU3F4 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2
- SLC24A3 | c.536del p.G179Efs*36 | Frame Shift Del (DEL) | VAF 20/186 reads (11%) | called by mutect2, pindel, varscan2
- SUPT20H | c.292+1del p.X98_splice (on ENST00000350612 / NM_001014286.3; = p.X99_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- TRAT1 | c.304del p.X102_splice | Splice Site (DEL) | VAF 44/257 reads (17%) | called by mutect2, pindel, varscan2
- ABHD16B | c.714C>G p.P238= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53861860, COSV99410634; called by muse, mutect2, varscan2
- ACSM3 | c.280C>A p.R94= | Silent (SNP) | VAF 118/276 reads (43%) | catalogued as COSV99184012, COSV99184393; called by muse, varscan2
- ADAMTS14 | c.1593C>A p.P531= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100941521; called by muse, mutect2, varscan2
- ARHGAP28 | c.1326T>G p.A442= (on ENST00000383472 / NM_001366230.1; = p.A283= on NM_001010000.3) | Silent (SNP) | VAF 133/223 reads (60%) | catalogued as COSV99149877; called by muse, mutect2, varscan2
- ASMT | c.513G>A p.V171= | Silent (SNP) | VAF 116/281 reads (41%) | catalogued as COSV101172440; called by muse, mutect2, varscan2
- BCAR1 | c.1347G>T p.P449= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV99366505; called by muse, mutect2, varscan2
- C16orf46 | c.984G>A p.Q328= | Silent (SNP) | VAF 73/198 reads (37%) | catalogued as rs1242292471, COSV100215254; called by muse, mutect2, varscan2
- C4orf3 | c.180C>G p.L60= | Silent (SNP) | VAF 81/149 reads (54%) | catalogued as rs766271124, COSV101208166; called by muse, mutect2, varscan2
- CDH10 | c.429G>A p.E143= | Silent (SNP) | VAF 97/226 reads (43%) | catalogued as COSV100051122; called by muse, mutect2, varscan2
- CDH9 | c.1638A>G p.T546= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as COSV99143652; called by muse, mutect2, varscan2
- CSMD2 | c.3201C>T p.P1067= | Silent (SNP) | VAF 104/244 reads (43%) | catalogued as rs145807635, COSV99591152, COSV99593968; called by muse, mutect2, varscan2
- CYP4F12 | c.1551G>A p.E517= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs747072393, COSV100215784; called by muse, mutect2, varscan2
- DKK2 | c.378C>T p.I126= | Silent (SNP) | VAF 89/204 reads (44%) | catalogued as COSV99568592; called by muse, mutect2, varscan2
- DNAH7 | c.8013T>A p.G2671= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV100414866; called by muse, mutect2, varscan2
- DPP10 | c.1068T>C p.C356= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV100063094; called by muse, mutect2, varscan2
- DPYD | c.2448C>T p.C816= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100928927; called by muse, mutect2
- DPYSL5 | c.1650T>C p.A550= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99982217; called by mutect2, varscan2
- DPYSL5 | c.1651C>A p.R551= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs373724609, COSV56510779; called by muse, mutect2, varscan2
- ELOA3B | c.819C>A p.P273= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- FAM181A | c.357G>T p.R119= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV99967818; called by muse, mutect2, varscan2
- FBN1 | c.5292C>T p.P1764= | Silent (SNP) | VAF 65/81 reads (80%) | catalogued as rs111756438, COSV100354658; ClinVar: likely benign; called by muse, mutect2, varscan2
- FRMD1 | c.763C>A p.R255= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV99349681; called by muse, mutect2, varscan2
- FYB1 | c.1263C>G p.P421= | Silent (SNP) | VAF 141/363 reads (39%) | catalogued as COSV100685165, COSV100685284; called by muse, mutect2, varscan2
- FYB2 | c.387A>G p.K129= | Silent (SNP) | VAF 128/323 reads (40%) | catalogued as rs746007976, COSV100599468; called by muse, mutect2, varscan2
- GALC | c.780A>G p.A260= | Silent (SNP) | VAF 79/180 reads (44%) | catalogued as COSV99729485; called by muse, mutect2, varscan2
- GANAB | c.1113C>T p.S371= | Silent (SNP) | VAF 183/418 reads (44%) | catalogued as COSV100647993; called by muse, mutect2, varscan2
- GLYR1 | c.1641G>T p.V547= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100424206; called by muse, mutect2, varscan2
- GPR149 | c.1533A>G p.P511= | Silent (SNP) | VAF 80/247 reads (32%) | catalogued as COSV101078363; called by muse, mutect2, varscan2
- GPRASP2 | c.1011G>A p.Q337= | Silent (SNP) | VAF 77/98 reads (79%) | catalogued as COSV100176679; called by muse, mutect2, varscan2
- GRK2 | c.780G>T p.A260= | Silent (SNP) | VAF 55/132 reads (42%) | catalogued as rs377123753; called by muse, mutect2, varscan2
- GUF1 | c.861A>G p.V287= | Silent (SNP) | VAF 94/133 reads (71%) | catalogued as COSV99877232; called by muse, mutect2, varscan2
- HCN1 | c.1143C>A p.V381= | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as rs761760627, COSV100299239, COSV100301749, COSV57540975; called by muse, mutect2, varscan2
- HNRNPF | c.927C>T p.F309= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as rs1191823622, COSV100563035; called by muse, mutect2, varscan2
- IFIH1 | c.2262G>C p.L754= | Silent (SNP) | VAF 97/140 reads (69%) | catalogued as COSV99718590; called by muse, mutect2, varscan2
- IGLV2-8 | c.6C>T p.A2= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1487878032; called by muse, mutect2, varscan2
- IMPG2 | c.2640G>T p.V880= | Silent (SNP) | VAF 70/116 reads (60%) | catalogued as COSV51987142, COSV99515654, COSV99516248; called by muse, mutect2, varscan2
- LAIR1 | c.423G>A p.T141= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs201544849, COSV57308356; called by muse, mutect2, varscan2
- LATS1 | c.2862A>T p.T954= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV99485767; called by muse, mutect2, varscan2
- LILRA1 | c.438C>A p.V146= | Silent (SNP) | VAF 82/195 reads (42%) | catalogued as COSV99251865; called by muse, mutect2, varscan2
- LMX1A | c.474G>A p.V158= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs940751887, COSV99672088; called by muse, mutect2, varscan2
- LRIT1 | c.1245G>T p.L415= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as COSV100928068; called by muse, mutect2, varscan2
- MSH4 | c.2607G>T p.T869= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV99591385; called by muse, mutect2, varscan2
- MTIF3 | c.600C>T p.D200= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs749259667, COSV100820191; called by muse, mutect2, varscan2
- MYH7 | c.4240C>T p.L1414= | Silent (SNP) | VAF 149/244 reads (61%) | catalogued as CM081706, COSV100806004; called by muse, mutect2, varscan2
- MYO18B | c.7461G>C p.G2487= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV100122633, COSV100123382, COSV59133056; called by muse, mutect2, varscan2
- NOX5 | c.1641G>T p.S547= | Silent (SNP) | VAF 44/52 reads (85%) | catalogued as COSV52986656, COSV99533711; called by muse, mutect2, varscan2
- OPRK1 | c.189G>C p.T63= | Silent (SNP) | VAF 29/40 reads (73%) | catalogued as COSV99653640; called by muse, mutect2, varscan2
- OR1J2 | c.912C>A p.L304= | Silent (SNP) | VAF 95/119 reads (80%) | catalogued as COSV58944666; called by muse, mutect2, varscan2
- OR2F2 | c.720G>T p.T240= | Silent (SNP) | VAF 47/75 reads (63%) | catalogued as COSV101283811, COSV68833140; called by muse, mutect2, varscan2
- OR2T6 | c.672A>T p.T224= | Silent (SNP) | VAF 81/149 reads (54%) | catalogued as COSV100861541; called by muse, mutect2, varscan2
- OR4C13 | c.279T>C p.N93= | Silent (SNP) | VAF 130/302 reads (43%) | catalogued as COSV101634170; called by muse, mutect2, varscan2
- OR51L1 | c.222G>C p.G74= | Silent (SNP) | VAF 98/272 reads (36%) | catalogued as COSV100386419, COSV58624671; called by muse, mutect2
- OR52N5 | c.435C>G p.L145= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as COSV100399666; called by muse, mutect2, varscan2
- OR5D16 | c.582T>A p.S194= | Silent (SNP) | VAF 71/200 reads (36%) | catalogued as COSV101003917; called by muse, mutect2, varscan2
- OR8K5 | c.279C>G p.S93= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as COSV100537200, COSV57890037, COSV57890925; called by muse, mutect2, varscan2
- P2RX3 | c.819C>T p.S273= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as rs778222206, COSV99628520; called by muse, mutect2, varscan2
- PCDHA6 | c.1566G>T p.P522= | Silent (SNP) | VAF 165/209 reads (79%) | catalogued as COSV100971428, COSV65344491; called by muse, mutect2, varscan2
- PCNT | c.4818G>A p.Q1606= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as rs750105722, COSV100855400; called by muse, mutect2, varscan2
- PIK3R6 | c.972C>A p.L324= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61006648; called by muse, mutect2, varscan2
- PKHD1 | c.228C>T p.P76= | Silent (SNP) | VAF 97/243 reads (40%) | catalogued as COSV100582657; called by muse, mutect2, varscan2
- PPP4R1 | c.1602A>T p.L534= (on ENST00000400556 / NM_001042388.3; = p.L517= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/227 reads (22%) | catalogued as COSV99553398; called by muse, mutect2, varscan2
- RAB3C | c.630G>A p.Q210= | Silent (SNP) | VAF 98/120 reads (82%) | catalogued as COSV99277228; called by muse, mutect2, varscan2
- RBX1 | c.30G>T p.P10= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV53429571, COSV99345387; called by muse, mutect2
- RNF20 | c.2298G>A p.E766= | Silent (SNP) | VAF 79/92 reads (86%) | catalogued as COSV101206519; called by muse, mutect2, varscan2
- SHANK2 | c.2724C>T p.C908= | Silent (SNP) | VAF 30/352 reads (9%) | catalogued as COSV99573483; called by muse, mutect2
- SI | c.3417C>A p.P1139= | Silent (SNP) | VAF 89/176 reads (51%) | catalogued as COSV100015062; called by muse, mutect2, varscan2
- SYNJ1 | c.3966A>T p.P1322= | Silent (SNP) | VAF 158/433 reads (36%) | catalogued as COSV100449225; called by muse, mutect2, varscan2
- SYT4 | c.1098C>A p.G366= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as COSV99673670; called by muse, mutect2, varscan2
- TMEM19 | c.249A>G p.L83= | Silent (SNP) | VAF 53/163 reads (33%) | catalogued as rs751656469, COSV99876918; called by muse, mutect2, varscan2
- TMIGD3 | c.684A>C p.V228= (on ENST00000369717 / NM_001081976.2; = p.V309= on NM_020683.7) | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as COSV100778401; called by muse, mutect2, varscan2
- TRIP12 | c.4665A>G p.A1555= | Silent (SNP) | VAF 55/75 reads (73%) | catalogued as COSV52264942, COSV99389960; called by muse, mutect2, varscan2
- TTN | c.31083C>G p.P10361= (on ENST00000591111; = p.P9434= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 93/166 reads (56%) | catalogued as COSV100607413; called by muse, mutect2, varscan2
- VPS37C | c.63G>T p.A21= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as COSV100075139; called by muse, mutect2, varscan2
- VPS50 | c.798A>G p.T266= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV99298055; called by muse, mutect2, varscan2
- XCR1 | c.825C>T p.L275= | Silent (SNP) | VAF 25/35 reads (71%) | catalogued as rs771639209, COSV100499347; called by muse, mutect2, varscan2
- YLPM1 | c.750G>T p.P250= | Silent (SNP) | VAF 108/166 reads (65%) | catalogued as COSV99459361; called by muse, mutect2, varscan2
- ZNF518A | c.2598A>T p.S866= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as COSV100283476; called by muse, mutect2, varscan2
- ATP2B2 | c.908-1183G>T | Intron (SNP) | VAF 57/82 reads (70%) | catalogued as COSV100659945; called by muse, mutect2, varscan2
- C3orf84 | c.141+154C>A | Intron (SNP) | VAF 126/167 reads (75%) | catalogued as COSV101410318; called by muse, mutect2, varscan2
- DCHS2 | n.3411G>T | RNA (SNP) | VAF 104/247 reads (42%) | catalogued as COSV100251604; called by muse, mutect2, varscan2
- EPDR1 | c.-46C>A | 5'UTR (SNP) | VAF 61/67 reads (91%) | catalogued as rs764329308, COSV99554366; called by muse, mutect2, varscan2
- KNOP1P1 | n.67G>C | RNA (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- MIR30A | n.2C>G | RNA (SNP) | VAF 13/21 reads (62%) | called by muse, mutect2, varscan2
- MIR514A1 | n.89G>T | RNA (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- OR2W5 | n.890T>C | RNA (SNP) | VAF 117/276 reads (42%) | called by muse, mutect2
- ST8SIA2 | chr15:92472202 C>A | 3'Flank (SNP) | VAF 75/92 reads (82%) | called by muse, mutect2
